Gene-level copy-number profile of tumor specimen TCGA-BC-A5W4-01A from TCGA case TCGA-BC-A5W4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.8 years (25,503 days).
Specimen TCGA-BC-A5W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.650035b5-2a2d-4c91-9c7b-b51c0920188f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A5W4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/59d2bf71-06d0-4e24-9925-d7d8d7bd9093

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 351; copy number 2: 14,685; copy number 3: 7,161; copy number 4: 30,827; copy number 5: 2,929; copy number 6: 2,966; copy number 7: 156; copy number 8: 712; copy number 9: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A5W4-01A-11D-A28W-01): tumor purity 0.93, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:142,728–287,215, 16 genes: HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1, FAM234A, RGS11, Z69667.1, ARHGDIG, PDIA2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:34,692,290–35,725,142, 11 genes, copy number 9: AC073218.1, AC012593.2, AC012593.1, RN7SL602P, AC019064.1, SMIM7P1, AC013442.1, MIR548AD, RNU6-1117P, AC083939.1, MRPL50P1.

Autosomal genes at a single copy (total copy number 1): 351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
